FM case AD12050 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/a0a330b8-734c-41ff-811f-a2caba7f1ffe

Male, 48.4 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
